MMRF case MMRF_2535 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e2740d98-bca8-4721-82cb-66fb80d2c343

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 565 days (1.5 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.6 years (17,034 days); ISS stage: III; Days to last known disease status: 565 days (1.5 years); Days to last follow up: 565 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 200 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 3 days; Days to treatment end: 200 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 17 days; Days to treatment end: 200 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 212 days; Days to treatment end: 212 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 213 days; Days to treatment end: 213 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 341 days; Days to treatment end: 358 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Other + Vincristine; Regimen or line of therapy: Second line of therapy; Days to treatment start: 342 days; Days to treatment end: 358 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 565.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 3 (ECOG 3): M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13 mg/dL; Immunoglobulin G 2.94 g/L; Immunoglobulin A 0.132 g/L; Immunoglobulin M 0.03 g/L; Beta 2 Microglobulin 13.6 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.54 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 297 µmol/L; Calcium 3.45 mmol/L; Albumin 35 g/L; Total Protein 5.3 g/dL; Glucose 5.12 mmol/L; C-Reactive Protein 0.12 mg/dL.
- Day 99 (ECOG 0): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.3 mg/dL; Immunoglobulin G 3.18 g/L; Immunoglobulin A 0.173 g/L; Immunoglobulin M 0.132 g/L; Beta 2 Microglobulin 3.8 µg/mL; Lactate Dehydrogenase 4.68 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.57 ×10⁹/L; Absolute Neutrophil 2.84 ×10⁹/L; Platelets 303 ×10⁹/L; Creatinine 70.7 µmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 4.62 mmol/L.
- Day 172 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.97 mg/dL; Immunoglobulin G 2.71 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.168 g/L; Beta 2 Microglobulin 2.72 µg/mL; Lactate Dehydrogenase 4.27 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.35 ×10⁹/L; Absolute Neutrophil 2.21 ×10⁹/L; Platelets 347 ×10⁹/L; Creatinine 76.9 µmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 5.5 mmol/L.
- Day 280 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 2.74 g/L; Immunoglobulin A 0.099 g/L; Immunoglobulin M 0.958 g/L; Beta 2 Microglobulin 4.39 µg/mL; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.41 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 72.5 µmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 4.95 mmol/L.
- Day 354: M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 69.4 mg/dL; Immunoglobulin G 2.94 g/L; Immunoglobulin A 0.083 g/L; Immunoglobulin M 0.083 g/L; Beta 2 Microglobulin 4.06 µg/mL; Lactate Dehydrogenase 4.13 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.13 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 84 µmol/L; Calcium 2.2 mmol/L; Albumin 41.8 g/L; Total Protein 6.3 g/dL; Glucose 5.34 mmol/L.
- Day 445: M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 136 mg/dL; Immunoglobulin G 2.03 g/L; Immunoglobulin A 0.091 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 4.12 µg/mL; Lactate Dehydrogenase 5.77 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.77 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 61 ×10⁹/L; Creatinine 103 µmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.4 g/dL; Glucose 7.21 mmol/L.
- Day 533: M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.86 mg/dL; Immunoglobulin G 8.5 g/L; Immunoglobulin A 0.302 g/L; Immunoglobulin M 0.126 g/L; Beta 2 Microglobulin 4.97 µg/mL; Lactate Dehydrogenase 6.25 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 7.74 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 15 ×10⁹/L; Creatinine 131 µmol/L; Calcium 2.23 mmol/L; Total Protein 7.4 g/dL; Glucose 7.81 mmol/L.

Other clinical attributes
- Day 3: Weight: 54 kg; Height: 163 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_2535_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 3 days.
- Sample MMRF_2535_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 3 days.
- Sample MMRF_2535_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 354 days.
